Gene-level copy-number profile of tumor specimen TCGA-A2-A0SU-01A from TCGA case TCGA-A2-A0SU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,219 days).
Specimen TCGA-A2-A0SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8d301711-4802-4905-ac86-8b13a545e414.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0SU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b528d7b9-f6ea-4a7d-9967-d2bf22ad418a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,131; copy number 4: 50,185; copy number 6: 1,337; copy number 8: 1,419; copy number 9: 12; copy number 14: 6; copy number 18: 130; copy number 19: 376; copy number 20: 101; copy number 21: 2; copy number 22: 50; copy number 23: 10; copy number 26: 56; copy number 27: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0SU-01A-11D-A087-01): tumor purity 0.56, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 747 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:24,252,749–30,660,770, 144 genes, copy number 19 (within-gene range 2–19) (broad region; genes not listed).
- chr13:91,087,254–91,354,579, 10 genes, copy number 23: LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:93,226,807–94,408,020, 1 gene, copy number 22 (within-gene range 4–22): GPC6.
- chr13:93,818,424–97,476,459, 49 genes, copy number 22: GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4.
- chr13:97,901,653–98,024,296, 4 genes, copy number 27: RPL7AP61, AL356580.1, IPO5, FTLP8.
- chr15:49,326,962–49,620,929, 1 gene, copy number 20 (within-gene range 2–20): FAM227B.
- chr15:49,423,237–54,633,414, 100 genes, copy number 20 (broad region; genes not listed).
- chr15:61,638,928–67,065,268, 152 genes, copy number 14–19 (within-gene range 2–19) (broad region; genes not listed).
- chr15:86,138,269–86,140,240, 2 genes, copy number 21: RNA5SP400, AC016180.2.
- chr15:90,229,975–90,386,063, 17 genes, copy number 19: CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4.
- chr15:90,393,490–90,397,881, 1 gene, copy number 19: AC018946.1.
- chr15:92,617,448–92,809,884, 1 gene, copy number 19 (within-gene range 4–19): FAM174B.
- chr15:92,699,040–101,933,350, 197 genes, copy number 19 (broad region; genes not listed).
- chr16:46,973,989–49,968,730, 68 genes, copy number 9–26 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
